Gene-level copy-number profile of tumor specimen TCGA-YU-A90W-01A from TCGA case TCGA-YU-A90W, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 45.2 years (16,497 days).
Specimen TCGA-YU-A90W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.7be5b074-da2d-49ec-ac3f-5dcdb9ba4bb1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YU-A90W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1c8f2fd7-1269-4461-b8eb-992b7290e0c8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,138; copy number 3: 8,728; copy number 4: 21,680; copy number 5: 5,484; copy number 6: 10,745; copy number 7: 4,966; copy number 8: 3,447; copy number 9: 1,744; copy number 10: 882.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YU-A90W-01A-11D-A434-01): tumor purity 0.51, ploidy 4.8, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,626 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:2,935,353–4,994,972, 1 gene, copy number 9 (within-gene range 8–9): CSMD1.
- chr8:4,317,388–10,055,041, 180 genes, copy number 9 (broad region; genes not listed).
- chr8:10,118,005–10,147,423, 1 gene, copy number 9 (within-gene range 8–9): AC023385.1.
- chr8:12,721,906–12,756,073, 1 gene, copy number 9 (within-gene range 8–9): LONRF1.
- chr8:12,765,849–20,226,819, 103 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr8:24,912,165–122,127,184, 1,478 genes, copy number 9–10 (broad region; genes not listed).
- chr8:135,859,369–138,914,041, 12 genes, copy number 9: LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1.
- chr12:66,767–34,249,958, 850 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
